Surgical pathology report (de-identified scan), TCGA case TCGA-LC-A66R, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Hartford Hospital, specimen TCGA-LC-A66R-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site Bladder NOS C67.9
JW 5/10/13

Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

LOCATION:
SUBMITTING MD:
CC:

DIAGNOSIS

1. LEFT DISTAL URETER, BIOPSY: BENIGN UROTHELIUM AND WALL; NO TUMOR.
2. LYMPH NODE, LEFT PELVIC, EXTENSION: ONE OUT OF ELEVEN LYMPH NODES POSITIVE FOR METASTATIC HIGH GRADE UROTHELIAL CARCINOMA (1/11).
3. RIGHT DISTAL URETER, BIOPSY: BENIGN UROTHELIUM AND WALL; NO TUMOR.
4. LYMPH NODE, RIGHT PELVIC, EXCISION: TWO OUT OF FIFTEEN LYMPH NODES POSITIVE FOR METASTATIC HIGH GRADE UROTHELIAL CARCINOMA (2/15).
5. BLADDER AND PROSTATE, RADICAL CYSTOPROSTATECTOMY: INVASIVE UROTHELIAL CARCINOMA

Histologic type:	Urothelial carcinoma
Histologic grade:	High grade/poorly differentiated
Tumor size:	8 cm
*Tumor site:	Bladder wall and prostatic urethra (with further invasion into prostate)
Tumor multicentricity:	Multicentric
Microscopic tumor extension:	Tumor invades into perivesical fat and prostatic stroma (apex).
Extravesical extension:	Present (tumor invades into prostatic stroma at the apex through prostatic urethra)
Vascular invasion:	Possible present
Perineural invasion:	Present
Associated epithelial lesions:	Non-invasive high grade urothelial carcinoma and carcinoma in situ
Margins:	Negative urethral, left and right ureter and radial margins
Prostate & seminal vesicles:	Prostate involved by tumor; negative seminal vesicles
Lymph nodes:	Three out of thirty-one lymph nodes positive (3/31), including specimens #3, #4 & #5
cTNM: (given by clinician)	Clinical stage III
pTNM:	pT4a, pN2
AJCC STAGE (2010):	Stage IV

6. LEFT URETER, TRUE MARGIN, EXCISION: UROTHELIUM WITH REACTIVE CHANGES; NO TUMOR.
7. RIGHT URETER, TRUE MARGIN, EXCISION: BENIGN UROTHELIUM AND WALL; NO TUMOR.

Electronically Signed Out

COMMENT

88305x4, 88307x2, 88309, 88331x2

ICD-O Discrepancy		☒
Site Discrepancy		☒
Quality/Quantity Discrepancy		☒
Case is (in)complete	☒	☐
Reviewed	9/8/13	

[page 2 of 3]
Clinical Diagnosis and History:

Bladder ca
Stage 3

Tissue(s) Submitted:

- 1: LEFT DISTAL URETER
- 2: LEFT PELVIC LYMPH NODES
- 3: RIGHT DISTAL URETER
- 4: RIGHT PELVIC LYMPH NODES
- 5: BLADDER AND PROSTATE
- 6: LEFT URETER TRUE MARGIN
- 7: RIGHT URETER TRUE MARGIN

Gross Description:

Specimen #1 is received fresh for intraoperative consultation labeled left distal ureter and consists of a 0.4 x 0.2 cm tubular tissue which is submitted in toto for frozen section diagnosis labeled FS1A. The frozen residue is submitted in the corresponding cassette.

Specimen #2 is received in formalin labeled left pelvic lymph nodes and consists of a 5.0 x 3.5 x 2.0 cm aggregate of fat which is palpated to reveal multiple nodes ranging from 0.1 cm to 3.0 cm in greatest dimension. The nodes are entirely submitted as follows:

- 2A: three possible nodes
- 2B: two possible nodes
- 2C-2F: each cassette containing one bisected node
- 2G-2I: one trisected node
- 2J-2M: one serially sectioned node
- 2N: 1 bisected node

Specimen #3 is received fresh for intraoperative consultation labeled right distal ureter and consists of a 0.6 x 0.4 cm tubular tissue which is submitted in toto for frozen section diagnosis labeled FS3A. The frozen residue is submitted in the corresponding cassette.

Specimen #4 is received in formalin labeled right pelvic lymph nodes and consists of a 5.0 x 3.0 x 2.0 cm aggregate of fat which is palpated to reveal multiple possible nodes ranging from 0.3 cm to 3.5 cm in greatest dimension. The nodes are entirely submitted as follows:

- 4A: four possible lobes
- 4B-4C: each cassette containing two nodes
- 4D-4G: each cassette containing one bisected node
- 4H-4I: one bisected node
- 4J-4K: one serially sectioned node
- 4L-4N: one serially sectioned node

Specimen #5 is received fresh labeled bladder and prostate and consists of a 12.5 x 11.0 x 5.0 cm bladder with attached 5.0 x 4.5 x 4.5 cm prostate. Extending from the prostatic urethra is a 35.0 x 0.7 cm catheter. Partially surfacing the posterior aspect is a 14.0 x 10.0 cm area of smooth peritoneum. Attached to the prostate are right and left vas deferens averaging 5.0 x 0.5 cm. The left seminal vesicle measures 4.5 x 2.0 x 1.0 cm and the right seminal vesicle 4.5 x 2.0 x 0.5 cm. The right half of the specimen is inked blue, the left half is inked black and the specimen is opened with a Y-shaped incision along the anterior aspect to reveal an 8.0 x 6.0 x 1.5 cm focally soft and necrotic papillary lesion involving the dome, posterior, anterior and left lateral wall of the bladder. Noted on the prostate, at the bladder base, are several papillary growths grossly not contiguous with the main mass measuring 1.0 cm in greatest dimension. Further sectioning reveals the mass effacing an area of muscle in the left lateral wall, focally possibly invading into the adipose tissue, 0.3 cm from the posterior ink. The tumor does not grossly appear to involve the ureter. Serial sectioning of the prostate reveals a 1.5 x 0.6 cm ill defined tan lesion in the right apex towards the posterior aspect, grossly abutting the inked capsule. Palpated are five possible nodes ranging from 0.1 cm to 1.5 cm in greatest dimension. Note that approximately 90% of the prostate is submitted. Representative sections are submitted as follows:

- 5A: possible urethral margin en face
- 5B-5C: perpendicular sections of right apical prostatic margin
- 5D-5E: perpendicular sections of left apical prostatic margin
- 5F-5G: bisected section of trigone with papillary growths near bladder base of prostate
- 5H: trigone with prostate to include papillary growths near prostatic bladder base
- 5I: right ureteral orifice
- 5J: left ureteral orifice
- 5K-5N: tumor to closest ink from left lateral wall (contiguous sections)
- 5O: tumor to left lateral wall with possibly involved fat
- 5P: tumor to possibly involved vessel from left lateral wall

[page 3 of 3]
5Q-5T: tumor to closest invasion to posterior ink
5U-5V: tumor in dome
5W-5Z: tumor in anterior wall
5AA-5CC: right lateral wall
5DD-5ZZ: right prostate
5AAA-5VVV: left prostate
5WWW-5XXX: bisected section of right prostate with seminal vesicle
5YYY-5ZZZ: left prostate with seminal vesicle
5AAAA: right and left vas deferens margin
5BBBB: three possible nodes
5CCCC: one bisected node
5DDDD: one bisected node

Specimen #6 is received in formalin labeled left ureter-true margin and consists of a 1.5 x 0.6 cm tubular tissue with an attached suture on one end. The specimen is entirely submitted as follows:

6A: sutured end
6B: middle cross sections
6C: end opposing suture

Specimen #7 is received in formalin labeled right ureter-true margin and consists of a 2.3 x 0.4 cm tubular tissue sutured on one end. The specimen is entirely submitted as follows:

7A: sutured end
7B: middle cross sections
7C: end opposing suture

Intraoperative Consult Diagnosis

1A/FSDX: URETER NEGATIVE FOR TUMOR.

3A/GDX/FSDX: URETER WITH ACUTE INFLAMMATION AND REACTIVE CHANGES; NO TUMOR.

Source: NCI Genomic Data Commons file efd4ad96-b4ac-4bff-ba85-f2cbab4083e9 (TCGA-LC-A66R.4E013D66-E9BD-49D1-8CA5-CABFE070D7BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).